Somatic mutation profile of tumor specimen TCGA-DD-AADM-01A (aliquot TCGA-DD-AADM-01A-11D-A40R-10) from TCGA case TCGA-DD-AADM, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 58.5 years (21,349 days).
Specimen TCGA-DD-AADM-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ab9164f-1a72-4aa0-a5dd-bdb60d8e7b00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADM-10A (Blood Derived Normal), aliquot TCGA-DD-AADM-10A-01D-A40U-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70f9a597-6e94-4cc7-a26e-dce3043fd7a1

The open-access MAF lists 216 somatic variants for this specimen: 159 protein-altering or splice-affecting, 54 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 131, Silent 54, Frame Shift Del 12, Frame Shift Ins 6, Nonsense Mutation 4, In Frame Del 3, Splice Site 2, 3'Flank 1, In Frame Ins 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.1161T>A p.N387K | Missense Mutation (SNP) | VAF 18/143 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs868651538, COSV62688055, COSV62689041; called by muse, mutect2, varscan2
- AASDH | c.108G>C p.K36N | Missense Mutation (SNP) | VAF 42/286 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.479); catalogued as COSV52709751, COSV99220913; called by muse, mutect2, varscan2
- ACSL3 | c.545A>G p.Y182C | Missense Mutation (SNP) | VAF 44/120 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100657874; called by muse, mutect2, varscan2
- ADGRL2 | c.4220A>G p.Y1407C (on ENST00000370717 / NM_001366005.1; = p.Y1351C on NM_012302.4) | Missense Mutation (SNP) | VAF 22/106 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV99587409; called by muse, mutect2, varscan2
- ADGRV1 | c.3377T>C p.I1126T | Missense Mutation (SNP) | VAF 18/240 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV101315552; called by muse, mutect2
- AK3 | c.583A>G p.T195A | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as COSV100729398; called by muse, mutect2, varscan2
- APC | c.3890A>G p.D1297G | Missense Mutation (SNP) | VAF 41/462 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV57384421, COSV99965860; called by muse, mutect2
- ARHGAP29 | c.3518T>G p.I1173S | Missense Mutation (SNP) | VAF 15/86 reads (17%) | SIFT tolerated (0.86); PolyPhen benign (0.001); catalogued as COSV99557739; called by muse, mutect2, varscan2
- ARHGEF40 | c.1816C>T p.P606S | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.53); PolyPhen benign (0.057); catalogued as COSV100070079; called by muse, mutect2, varscan2
- ARMCX2 | c.1168A>G p.K390E | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100168061; called by muse, mutect2, varscan2
- ASAH2 | c.220A>T p.T74S | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100269821; called by muse, mutect2, varscan2
- BOP1 | c.1249C>T p.R417W | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs991635176; called by muse, mutect2, varscan2
- BPIFA3 | c.325T>C p.S109P | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV100967007; called by muse, mutect2, varscan2
- BPNT1 | c.802A>C p.N268H | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as COSV100435582; called by muse, mutect2, varscan2
- BUB1 | c.2850T>A p.S950R | Missense Mutation (SNP) | VAF 21/98 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100240975; called by muse, mutect2, varscan2
- C1orf112 | c.329A>T p.Y110F | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99609481; called by muse, mutect2
- CACNB1 | c.1664A>G p.Y555C | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as COSV100703327; called by muse, mutect2, varscan2
- CATSPERE | c.288A>T p.E96D | Missense Mutation (SNP) | VAF 37/178 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100834956; called by muse, mutect2, varscan2
- CBLN2 | c.587A>G p.D196G | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99504177; called by muse, mutect2, varscan2
- CCT4 | c.298A>G p.I100V | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.85); PolyPhen benign (0.021); catalogued as rs770614399, COSV101075077; called by muse, mutect2, varscan2
- CD2AP | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 44/418 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV100830345; called by muse, mutect2, varscan2
- CD36 | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 27/156 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV59211141, COSV99987238; called by muse, mutect2, varscan2
- CNOT2 | c.676G>T p.D226Y | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV99972432; called by muse, mutect2, varscan2
- CNTLN | c.1376C>T p.T459M | Missense Mutation (SNP) | VAF 79/400 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.742); catalogued as rs757011942, COSV52085057; called by muse, mutect2, varscan2
- COL5A1 | c.1528G>C p.D510H | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100879611; called by muse, mutect2, varscan2
- COPA | c.337G>T p.D113Y | Missense Mutation (SNP) | VAF 145/213 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99614829; called by muse, mutect2, varscan2
- CPEB2 | c.1994A>G p.D665G | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.954); catalogued as COSV99470034; called by muse, mutect2, varscan2
- CR1L | c.932G>C p.G311A | Missense Mutation (SNP) | VAF 48/712 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99686894; called by muse, mutect2
- CRIP3 | c.134C>A p.A45E | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1454749341, COSV99240162; called by muse, mutect2
- CRIPT | c.132dup p.A45Sfs*4 | Frame Shift Ins (INS) | VAF 71/574 reads (12%) | catalogued as rs771238795; called by mutect2, varscan2
- CXCL14 | c.130C>T p.P44S (on ENST00000337225; = p.P32S on NM_004887.5) | Missense Mutation (SNP) | VAF 13/131 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100463513; called by muse, mutect2, varscan2
- CYC1 | c.276dup p.S93Qfs*26 | Frame Shift Ins (INS) | VAF 16/46 reads (35%) | catalogued as rs756254049; called by mutect2, varscan2
- DBH | c.485A>T p.E162V | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV99707945; called by muse, mutect2, varscan2
- DDI1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.346); catalogued as COSV100158121; called by muse, mutect2, varscan2
- DHRS13 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 80/187 reads (43%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.961); catalogued as rs756925355, COSV100241603; called by muse, mutect2, varscan2
- DISC1 | c.434A>G p.Q145R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.311); catalogued as COSV99697294; called by muse, mutect2, varscan2
- DNAH7 | c.11419C>T p.Q3807* | Nonsense Mutation (SNP) | VAF 44/105 reads (42%) | catalogued as rs867446312, COSV100414139, COSV56761586, COSV56774674; called by muse, mutect2, varscan2
- DOCK2 | c.4759C>T p.H1587Y | Missense Mutation (SNP) | VAF 33/209 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV56959377, COSV99915305; called by muse, mutect2, varscan2
- ESCO1 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141644808; called by muse, mutect2, varscan2
- FAM151B | c.541A>G p.S181G | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.077); catalogued as rs200357393; called by muse, mutect2
- FAT1 | c.10348C>T p.Q3450* | Nonsense Mutation (SNP) | VAF 17/102 reads (17%) | catalogued as rs1437456803, COSV71674761; called by muse, mutect2, varscan2
- FCN1 | c.37G>A p.A13T | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as rs773091298, COSV65662050; called by mutect2, varscan2
- FGA | c.118G>A p.V40M | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.112); catalogued as COSV100120100; called by muse, mutect2, varscan2
- FLT4 | c.3095A>T p.K1032M | Missense Mutation (SNP) | VAF 11/167 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99986135; called by muse, mutect2
- G2E3 | c.205A>G p.I69V | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV99249372; called by muse, mutect2, varscan2
- GPT | c.665A>C p.H222P | Missense Mutation (SNP) | VAF 51/217 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.317); catalogued as COSV99477447; called by muse, mutect2, varscan2
- GRIN1 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as COSV100159902; called by muse, mutect2, varscan2
- GRIP1 | c.2423C>T p.S808L (on ENST00000359742 / NM_001379345.1; = p.S756L on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.835); catalogued as rs1244319253, COSV99668344; called by muse, mutect2, varscan2
- GSG1L | c.803C>A p.P268H (on ENST00000447459 / NM_001109763.2; = p.P113H on NM_144675.2) | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as COSV66581291; called by muse, mutect2, varscan2
- HDAC6 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 24/33 reads (73%) | SIFT tolerated (0.23); PolyPhen benign (0.383); catalogued as COSV100490623; called by muse, mutect2, varscan2
- HLX | c.1213A>G p.T405A | Missense Mutation (SNP) | VAF 65/313 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as COSV100854472; called by muse, varscan2
- HMCN1 | c.8453T>C p.L2818P | Missense Mutation (SNP) | VAF 20/136 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99625163; called by muse, mutect2, varscan2
- IRX5 | c.638C>G p.P213R | Missense Mutation (SNP) | VAF 93/316 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV100315657, COSV100316004; called by muse, mutect2, varscan2
- ITPKB | c.1871A>G p.E624G | Missense Mutation (SNP) | VAF 29/386 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99683840; called by muse, mutect2
- JAM2 | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 91/601 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100467904; called by muse, mutect2, varscan2
- JHY | c.1265A>G p.N422S | Missense Mutation (SNP) | VAF 66/184 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs201888967, COSV99912813; called by muse, mutect2, varscan2
- KAT6A | c.571G>T p.V191L | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.437); catalogued as rs1057523324, COSV99704521; ClinVar: uncertain significance; called by muse, mutect2
- KEAP1 | c.932A>T p.H311L | Missense Mutation (SNP) | VAF 50/94 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV50274684, COSV50325697, COSV50579650; called by muse, mutect2, varscan2
- KEAP1 | c.503T>G p.V168G | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV99407414; called by muse, mutect2, varscan2
- KIN | c.260A>G p.K87R | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.007); catalogued as COSV101092437; called by muse, mutect2, varscan2
- KLHL23 | c.1310A>G p.Q437R | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55870063; called by muse, mutect2
- KPNA4 | c.937A>G p.T313A | Missense Mutation (SNP) | VAF 85/233 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100515036; called by muse, mutect2, varscan2
- KRT37 | c.1205C>A p.A402D | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.419); catalogued as COSV99845295; called by muse, mutect2, varscan2
- LDB1 | c.229C>T p.R77W (on ENST00000425280 / NM_001321612.2; = p.R41W on NM_003893.5) | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762616778, COSV100756328; called by muse, mutect2, varscan2
- LEO1 | c.599A>T p.E200V | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.27); catalogued as COSV100166417; called by muse, mutect2, varscan2
- LHFPL1 | c.107C>G p.S36C | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.67); catalogued as COSV100914430; called by muse, mutect2, varscan2
- LMAN1L | c.691G>T p.V231F | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV100547594, COSV100547844; called by muse, mutect2, varscan2
- LSAMP | c.929C>T p.S310L | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs759178720, COSV61284633; called by muse, mutect2, varscan2
- MAP3K4 | c.3635C>G p.S1212C | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV100815097, COSV62335272; called by muse, mutect2
- MARVELD2 | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.006); catalogued as rs746116082, COSV100347419, COSV57782201; called by mutect2, varscan2
- MKI67 | c.5296G>T p.E1766* | Nonsense Mutation (SNP) | VAF 10/83 reads (12%) | catalogued as COSV100896245; called by muse, mutect2, varscan2
- MRGPRX2 | c.210C>G p.S70R | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as COSV100316647; called by muse, mutect2, varscan2
- MTREX | c.703A>T p.M235L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100043607; called by muse, mutect2, varscan2
- MTTP | c.925C>G p.R309G | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs756001078, COSV99644819; called by muse, mutect2, varscan2
- NEMF | c.2426A>C p.K809T | Missense Mutation (SNP) | VAF 43/276 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0.15); catalogued as COSV100027449; called by muse, mutect2, varscan2
- NMBR | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs758915165, COSV57800805; called by muse, mutect2, varscan2
- NT5C1B | c.1345T>G p.F449V (on ENST00000359846 / NM_001199086.2; = p.F389V on NM_033253.4) | Missense Mutation (SNP) | VAF 63/352 reads (18%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.593); catalogued as COSV100409818; called by muse, mutect2, varscan2
- NTRK2 | c.1285del p.E429Nfs*10 | Frame Shift Del (DEL) | VAF 20/173 reads (12%) | catalogued as COSV52862947, COSV52868949; called by mutect2, pindel, varscan2
- NUP214 | c.422A>G p.Y141C | Missense Mutation (SNP) | VAF 43/137 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.009); catalogued as rs772631965, COSV100845167; called by muse, mutect2, varscan2
- OR2G6 | c.553A>C p.I185L | Missense Mutation (SNP) | VAF 18/250 reads (7%) | SIFT tolerated (0.95); PolyPhen benign (0.078); catalogued as COSV100598047; called by muse, mutect2
- PCDHGB1 | c.745C>G p.Q249E | Missense Mutation (SNP) | VAF 49/239 reads (21%) | SIFT tolerated (0.55); PolyPhen benign (0.158); catalogued as COSV99532582, COSV99546161; called by muse, mutect2, varscan2
- PCLO | c.5923A>G p.T1975A | Missense Mutation (SNP) | VAF 30/154 reads (19%) | SIFT tolerated (0.39); PolyPhen benign (0.006); catalogued as COSV100428246; called by muse, mutect2
- PCLO | c.5921T>C p.L1974P | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV100428253; called by muse, mutect2
- PHKA1 | c.2316G>C p.E772D | Missense Mutation (SNP) | VAF 42/116 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100262589; called by muse, varscan2
- PHKA1 | c.2266G>C p.D756H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.828); catalogued as COSV100262590; called by muse, varscan2
- PI4KA | c.1129A>G p.M377V | Missense Mutation (SNP) | VAF 35/91 reads (38%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1333881705, COSV55410643; called by muse, mutect2, varscan2
- PKN3 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs1194287170, COSV99403338; called by muse, mutect2, varscan2
- PPP1R10 | c.2609A>T p.H870L | Missense Mutation (SNP) | VAF 16/121 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV100919761; called by muse, mutect2, varscan2
- PPP1R8 | c.433G>A p.G145R | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (0.49); PolyPhen benign (0.11); catalogued as COSV99360850; called by muse, mutect2, varscan2
- PRORP | c.1231C>G p.L411V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV51622854; called by muse, mutect2, varscan2
- PRPH2 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs61755785, CM941208, COSV100027974; ClinVar: not provided; called by muse, mutect2, varscan2
- PSMD12 | c.680A>G p.Y227C | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.656); catalogued as rs1324877809, COSV100635282; called by muse, mutect2, varscan2
- PTGER1 | c.1188C>G p.H396Q | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV99466277; called by muse, mutect2, varscan2
- PTGER3 | c.217G>T p.V73L | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT tolerated (1); PolyPhen probably damaging (0.946); catalogued as COSV100138406; called by muse, mutect2, varscan2
- PUS10 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100369424; called by muse, varscan2
- QSOX2 | c.1724A>G p.Q575R | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.55); PolyPhen benign (0.005); catalogued as rs1025997751, COSV100699706; called by muse, mutect2, varscan2
- RAB23 | c.405A>T p.E135D | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV100443734; called by muse, mutect2, varscan2
- RABEP1 | c.2496A>T p.L832F | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99336373; called by muse, mutect2, varscan2
- RELN | c.7876C>G p.L2626V | Missense Mutation (SNP) | VAF 44/93 reads (47%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as COSV100632711; called by muse, mutect2, varscan2
- RHBDD2 | c.241A>G p.I81V | Missense Mutation (SNP) | VAF 25/128 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs782246048, COSV99138193; called by muse, mutect2, varscan2
- RIN3 | c.1283A>G p.E428G | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV53655889; called by muse, mutect2, varscan2
- RND1 | c.134C>T p.T45I | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100552095; called by muse, mutect2, varscan2
- RNF145 | c.460C>T p.L154F (on ENST00000424310 / NM_001199383.2; = p.L182F on NM_144726.2) | Missense Mutation (SNP) | VAF 136/647 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99193278; called by muse, mutect2, varscan2
- RUFY4 | c.722A>G p.Q241R | Missense Mutation (SNP) | VAF 74/326 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100722959; called by muse, mutect2, varscan2
- SAXO1 | c.1226C>A p.T409N | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV101000119; called by muse, mutect2, varscan2
- SOX6 | c.731T>C p.L244P | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV100321379, COSV57046383; called by muse, mutect2, varscan2
- SPAG1 | c.2219T>C p.L740P | Missense Mutation (SNP) | VAF 162/604 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.169); catalogued as COSV99308472; called by muse, varscan2
- SPATA18 | c.407A>G p.N136S | Missense Mutation (SNP) | VAF 13/123 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV99730135; called by muse, mutect2, varscan2
- SPHKAP | c.2142A>T p.L714F | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100763769; called by muse, mutect2, varscan2
- SUN5 | c.890T>C p.V297A | Missense Mutation (SNP) | VAF 26/148 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.191); catalogued as COSV100644788; called by muse, mutect2, varscan2
- TENM3 | c.7843G>A p.E2615K | Missense Mutation (SNP) | VAF 11/44 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs762365565, COSV101304927; called by muse, mutect2
- TFEB | c.938G>T p.W313L | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100026013; called by muse, mutect2
- TMEM132A | c.2146C>A p.P716T (on ENST00000453848 / NM_178031.3; = p.P717T on NM_017870.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.38); PolyPhen benign (0.172); catalogued as COSV99134163; called by muse, mutect2, varscan2
- TMEM81 | c.34A>T p.S12C | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.639); catalogued as COSV52704863; called by muse, mutect2
- TNIP3 | c.314A>T p.E105V | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as COSV99284343; called by muse, mutect2, varscan2
- TRPC4 | c.1550T>C p.L517S | Missense Mutation (SNP) | VAF 36/141 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100156089; called by muse, mutect2, varscan2
- TRPV5 | c.2173G>T p.E725* | Nonsense Mutation (SNP) | VAF 33/236 reads (14%) | catalogued as COSV54686038, COSV54686752; called by muse, mutect2, varscan2
- TRPV5 | c.185G>T p.R62M | Missense Mutation (SNP) | VAF 26/164 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.69); catalogued as rs759831853, COSV99520168; called by muse, mutect2, varscan2
- TTC21A | c.422G>C p.R141T | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV100072984; called by muse, mutect2, varscan2
- TTN | c.27740A>G p.Y9247C (on ENST00000591111; = p.Y8320C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/139 reads (17%) | PolyPhen probably damaging (0.999); catalogued as COSV100598126; called by muse, mutect2, varscan2
- TTYH1 | c.1269-1G>A p.X423_splice | Splice Site (SNP) | VAF 35/88 reads (40%) | catalogued as COSV100001809; called by muse, mutect2, varscan2
- UMOD | c.844T>G p.C282G | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM034990, COSV100208058; called by muse, mutect2, varscan2
- USP45 | c.2233G>C p.G745R | Missense Mutation (SNP) | VAF 58/142 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100569517; called by muse, mutect2, varscan2
- VAV3 | c.327A>G p.I109M | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.712); catalogued as COSV100579259; called by muse, mutect2, varscan2
- WNK1 | c.3411A>T p.L1137F (on ENST00000315939 / NM_018979.4; = p.L890F on NM_014823.3) | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100266424; called by muse, mutect2, varscan2
- WRN | c.2015G>A p.C672Y | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99988415; called by muse, mutect2, varscan2
- ZKSCAN8 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 80/159 reads (50%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV100362829, COSV57639464; called by muse, mutect2, varscan2
- ZNF215 | c.220C>A p.L74I | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.033); catalogued as COSV99549297; called by muse, mutect2, varscan2
- ZNF561 | c.605G>A p.C202Y | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.77); catalogued as COSV100254321; called by muse, mutect2, varscan2
- ZNF573 | c.1369C>A p.L457I (on ENST00000536220 / NM_001172692.1; = p.L399I on NM_152360.3) | Missense Mutation (SNP) | VAF 39/211 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV100265467; called by muse, mutect2, varscan2
- ZNF577 | c.1261G>A p.G421R | Missense Mutation (SNP) | VAF 12/148 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV56815824, COSV56816339; called by muse, mutect2
- ZNF625 | c.875A>G p.Y292C | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.944); catalogued as rs767081402, COSV100863451; called by muse, mutect2, varscan2
- ZNF660 | c.226A>G p.K76E | Missense Mutation (SNP) | VAF 18/179 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.353); catalogued as COSV100502653; called by muse, mutect2, varscan2
- ZNF680 | c.419A>C p.N140T | Missense Mutation (SNP) | VAF 44/200 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.098); catalogued as COSV100548979; called by muse, mutect2, varscan2
- ZNF776 | c.493A>G p.I165V | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.018); catalogued as COSV100414103; called by muse, mutect2, varscan2
- ZNF800 | c.1121T>C p.L374P | Missense Mutation (SNP) | VAF 31/135 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99757717; called by muse, mutect2, varscan2
- ZNF98 | c.653C>A p.A218D | Missense Mutation (SNP) | VAF 147/485 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV100757334; called by muse, mutect2, varscan2
- ZRANB2 | c.302-2A>G p.X101_splice | Splice Site (SNP) | VAF 13/425 reads (3%) | catalogued as COSV99639052; called by muse, mutect2
- ADCY2 | c.68_69insGGG p.G23dup | In Frame Ins (INS) | VAF 18/84 reads (21%) | called by mutect2, pindel, varscan2
- ARID1B | c.2009del p.G670Afs*14 | Frame Shift Del (DEL) | VAF 7/64 reads (11%) | called by mutect2, pindel, varscan2
- C6orf47 | c.389_436del p.V130_L145del | In Frame Del (DEL) | VAF 35/120 reads (29%) | called by mutect2, pindel
- CCDC14 | c.2082dup p.S695* (on ENST00000488653; = p.S647* on NM_022757.5) | Frame Shift Ins (INS) | VAF 21/91 reads (23%) | called by mutect2, pindel, varscan2
- CCDC50 | c.678del p.K226Nfs*22 | Frame Shift Del (DEL) | VAF 21/166 reads (13%) | called by mutect2, varscan2
- CDKAL1 | c.667del p.T223Lfs*16 | Frame Shift Del (DEL) | VAF 56/230 reads (24%) | called by mutect2, pindel, varscan2
- CDKN2A | c.114del p.N39Tfs*14 | Frame Shift Del (DEL) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- CFAP74 | c.617T>A p.L206H | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CNOT6L | c.99dup p.S34Ifs*11 (on ENST00000504123 / NM_001286790.2; = p.S29Ifs*11 on NM_144571.3 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 27/99 reads (27%) | called by mutect2, pindel, varscan2
- MROH8 | c.1532C>T p.P511L | Missense Mutation (SNP) | VAF 16/134 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NGEF | c.1123_1124dup p.T376Gfs*16 | Frame Shift Ins (INS) | VAF 15/98 reads (15%) | called by mutect2, pindel, varscan2
- PKD2L2 | c.360_362del p.Y121del | In Frame Del (DEL) | VAF 64/112 reads (57%) | called by pindel, varscan2
- PPP1CA | c.902_911del p.K301Rfs*9 | Frame Shift Del (DEL) | VAF 15/95 reads (16%) | called by mutect2, pindel, varscan2
- RB1 | c.756del p.R254Gfs*10 | Frame Shift Del (DEL) | VAF 30/212 reads (14%) | called by mutect2, pindel, varscan2
- RBL2 | c.3008dup p.D1004Rfs*15 | Frame Shift Ins (INS) | VAF 25/188 reads (13%) | called by mutect2, pindel, varscan2
- RBM10 | c.958_969del p.L320_Y323del | In Frame Del (DEL) | VAF 25/112 reads (22%) | called by mutect2, pindel, varscan2
- SNX29 | c.1960_1969del p.N654* | Frame Shift Del (DEL) | VAF 29/91 reads (32%) | called by mutect2, pindel, varscan2
- STIL | c.1999_2036del p.P667Yfs*2 | Frame Shift Del (DEL) | VAF 16/127 reads (13%) | called by mutect2, pindel
- TRIT1 | c.1068del p.E357Sfs*25 | Frame Shift Del (DEL) | VAF 136/453 reads (30%) | called by mutect2, pindel, varscan2
- XPO6 | c.265_281del p.S89Pfs*6 | Frame Shift Del (DEL) | VAF 20/143 reads (14%) | called by mutect2, pindel
- ZNF3 | c.613_634del p.C205Lfs*213 | Frame Shift Del (DEL) | VAF 24/178 reads (13%) | called by mutect2, pindel, varscan2
- ADAM22 | c.1581T>A p.I527= | Silent (SNP) | VAF 21/212 reads (10%) | catalogued as COSV99716002; called by muse, mutect2
- ADAP1 | c.357C>T p.I119= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as COSV99762824; called by muse, mutect2
- ADIPOR1 | c.18A>T p.G6= | Silent (SNP) | VAF 10/158 reads (6%) | catalogued as COSV100579424; called by muse, mutect2
- ASMT | c.1029C>G p.A343= (on ENST00000381229; = p.A371= on NM_004043.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/274 reads (14%) | catalogued as COSV101172417; called by muse, mutect2, varscan2
- CCDC172 | c.7T>C p.L3= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs762316761, COSV60936861; called by muse, mutect2, varscan2
- CHST12 | c.162G>A p.P54= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as rs142111836; called by muse, mutect2, varscan2
- CLEC4G | c.342G>C p.A114= | Silent (SNP) | VAF 13/35 reads (37%) | catalogued as COSV100183592; called by muse, mutect2, varscan2
- CNTRL | c.1302A>G p.P434= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as COSV99441325; called by muse, mutect2, varscan2
- CREBBP | c.1071G>A p.Q357= | Silent (SNP) | VAF 56/125 reads (45%) | catalogued as COSV99268845; called by muse, mutect2, varscan2
- CYP2D6 | c.297C>G p.A99= | Silent (SNP) | VAF 17/276 reads (6%) | catalogued as rs200269944, COSV100637252; called by muse, mutect2
- DCC | c.4335A>C p.S1445= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV101472453; called by muse, mutect2, varscan2
- DCLK1 | c.975G>A p.P325= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs151019237, COSV55190671, COSV99709400; called by muse, mutect2, varscan2
- DZIP3 | c.2238T>A p.T746= | Silent (SNP) | VAF 149/402 reads (37%) | catalogued as COSV100847667; called by muse, mutect2, varscan2
- ERBB2 | c.1590C>T p.N530= | Silent (SNP) | VAF 19/85 reads (22%) | catalogued as rs957422814, COSV99506952; called by muse, mutect2, varscan2
- GPR22 | c.1011A>G p.L337= | Silent (SNP) | VAF 32/384 reads (8%) | catalogued as COSV99771512; called by muse, mutect2
- GRIP1 | c.2424A>C p.S808= (on ENST00000359742 / NM_001379345.1; = p.S756= on NM_021150.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 8/65 reads (12%) | catalogued as COSV99668340; called by muse, mutect2, varscan2
- HMCN1 | c.15444T>C p.I5148= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV99625165; called by muse, mutect2
- ID3 | c.343A>C p.R115= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as COSV101000744, COSV101000754; called by muse, mutect2, varscan2
- IRS2 | c.1647G>T p.L549= | Silent (SNP) | VAF 38/91 reads (42%) | catalogued as COSV101018863; called by muse, mutect2, varscan2
- JHY | c.384T>C p.Y128= | Silent (SNP) | VAF 18/163 reads (11%) | catalogued as COSV99912811; called by muse, mutect2
- KIF14 | c.3102G>A p.L1034= | Silent (SNP) | VAF 8/123 reads (7%) | catalogued as COSV100950660; called by muse, mutect2
- KIFC3 | c.594G>A p.L198= | Silent (SNP) | VAF 27/105 reads (26%) | catalogued as COSV101109101; called by muse, mutect2, varscan2
- KIR2DL4 | c.399C>T p.T133= (on ENST00000396284; = p.T94= on NM_001080770.2) | Silent (SNP) | VAF 42/88 reads (48%) | called by muse, mutect2, varscan2
- KLHL30 | c.1557C>T p.G519= | Silent (SNP) | VAF 24/222 reads (11%) | catalogued as rs1193070255, COSV100014045, COSV59975838; called by muse, mutect2, varscan2
- KMT2D | c.11394C>T p.P3798= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV99978276; called by muse, mutect2
- MALT1 | c.1548A>G p.K516= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV100618607; called by muse, mutect2, varscan2
- MED14 | c.3192A>G p.S1064= | Silent (SNP) | VAF 45/163 reads (28%) | catalogued as rs756084159, COSV100247354; called by muse, mutect2, varscan2
- MGA | c.7497A>G p.V2499= (on ENST00000219905 / NM_001164273.1; = p.V2290= on NM_001080541.2) | Silent (SNP) | VAF 59/224 reads (26%) | catalogued as rs1487670268, COSV99578824; called by muse, mutect2, varscan2
- MMP16 | c.1254T>C p.T418= | Silent (SNP) | VAF 61/350 reads (17%) | catalogued as COSV99686431; called by muse, mutect2, varscan2
- MOV10 | c.1536G>A p.T512= | Silent (SNP) | VAF 57/234 reads (24%) | catalogued as rs754526699, COSV62492489; called by muse, mutect2, varscan2
- MROH5 | c.3549C>T p.A1183= | Silent (SNP) | VAF 69/295 reads (23%) | catalogued as rs1292839582, COSV100267108; called by muse, mutect2, varscan2
- MTUS1 | c.1218C>T p.G406= | Silent (SNP) | VAF 49/81 reads (60%) | catalogued as COSV100029053; called by muse, mutect2, varscan2
- MUC2 | c.1407C>T p.N469= | Silent (SNP) | VAF 56/173 reads (32%) | catalogued as rs746178862; called by muse, mutect2, varscan2
- NEGR1 | c.129G>T p.A43= | Silent (SNP) | VAF 26/343 reads (8%) | catalogued as rs1220186249, COSV100747392, COSV63236846; called by muse, mutect2
- OLFM4 | c.1497G>C p.L499= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV99524216; called by muse, mutect2, varscan2
- OR5AR1 | c.330T>A p.A110= | Silent (SNP) | VAF 15/84 reads (18%) | catalogued as COSV100265588; called by muse, mutect2, varscan2
- PHTF2 | c.807A>G p.K269= (on ENST00000248550 / NM_001366089.1; = p.K231= on NM_020432.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 22/111 reads (20%) | catalogued as rs1257351189, COSV99301178; called by muse, mutect2, varscan2
- PIK3CB | c.18A>C p.I6= | Silent (SNP) | VAF 45/333 reads (14%) | catalogued as COSV100005287; called by muse, mutect2, varscan2
- RALGAPA2 | c.3870C>T p.A1290= | Silent (SNP) | VAF 10/27 reads (37%) | catalogued as COSV99173200; called by muse, mutect2, varscan2
- RBPJ | c.1374A>T p.G458= | Silent (SNP) | VAF 37/233 reads (16%) | catalogued as rs1058611, COSV100623536; called by muse, mutect2, varscan2
- RIF1 | c.177T>G p.V59= | Silent (SNP) | VAF 86/736 reads (12%) | catalogued as rs1047289023, COSV99690176; called by muse, mutect2, varscan2
- SERPINB10 | c.555C>T p.N185= | Silent (SNP) | VAF 29/111 reads (26%) | catalogued as rs550376818, COSV53071921; called by muse, mutect2, varscan2
- SFI1 | c.2184G>A p.V728= (on ENST00000400288 / NM_001007467.3; = p.V697= on NM_014775.4) | Silent (SNP) | VAF 8/70 reads (11%) | catalogued as COSV101191975; called by muse, mutect2
- SLC10A1 | c.618T>A p.S206= | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV99384223; called by muse, mutect2, varscan2
- SPRR2B | c.90G>T p.P30= | Silent (SNP) | VAF 9/71 reads (13%) | catalogued as COSV100482202, COSV100482274; called by muse, mutect2, varscan2
- SPRY3 | c.534T>C p.A178= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as COSV100249214; called by muse, mutect2, varscan2
- TDRD5 | c.348A>G p.R116= | Silent (SNP) | VAF 37/307 reads (12%) | catalogued as COSV99675647; called by muse, mutect2, varscan2
- TFEB | c.936C>G p.L312= | Silent (SNP) | VAF 28/107 reads (26%) | catalogued as COSV100026015; called by muse, mutect2
- TNFRSF13B | c.804G>T p.L268= | Silent (SNP) | VAF 21/106 reads (20%) | catalogued as COSV99890599; called by muse, mutect2, varscan2
- TRIM42 | c.756C>A p.I252= | Silent (SNP) | VAF 16/73 reads (22%) | catalogued as COSV99648050; called by muse, mutect2, varscan2
- TTK | c.186A>T p.P62= | Silent (SNP) | VAF 35/153 reads (23%) | catalogued as COSV100036046; called by muse, mutect2, varscan2
- VASH2 | c.144G>A p.L48= | Silent (SNP) | VAF 57/156 reads (37%) | catalogued as COSV99663437; called by muse, mutect2, varscan2
- ZNF396 | c.543T>G p.L181= | Silent (SNP) | VAF 48/87 reads (55%) | catalogued as COSV100108484; called by muse, mutect2, varscan2
- ZNF98 | c.654C>T p.A218= | Silent (SNP) | VAF 148/490 reads (30%) | catalogued as COSV100757332; called by muse, mutect2, varscan2
- COPS9 | chr2:240126759 T>G | 3'Flank (SNP) | VAF 17/144 reads (12%) | catalogued as COSV100216946; called by muse, mutect2
- FOLH1B | n.1275G>A | RNA (SNP) | VAF 106/892 reads (12%) | catalogued as rs762288383; called by muse, varscan2
- NCF4 | c.759-39A>T | Intron (SNP) | VAF 20/161 reads (12%) | catalogued as COSV99957142; called by muse, mutect2, varscan2
